Gene-level copy-number profile of tumor specimen ALCH-ADTF-TTP1-A from ALCHEMIST case ALCH-ADTF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.1 years (21,949 days).
Specimen ALCH-ADTF-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1196687d-c4f0-48bf-8396-8e47bf301cc0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADTF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/e6da71e8-dce8-479a-8258-5f412e8458b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 1: 2,798; copy number 2: 53,794; copy number 3: 1,699; copy number 4: 24.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,326,201–2,326,693, 1 gene (within-gene range 0–1): AL589739.1.
- chr3:9,600,748–9,602,728, 1 gene: DUSP5P2.
- chr5:174,724,582–174,730,896, 1 gene: MSX2.
- chr5:174,751,734–174,751,787, 1 gene (within-gene range 0–2): MIR4634.
- chr6:89,829,894–89,874,436, 2 genes: CASP8AP2, Y_RNA.
- chr8:55,449,509–55,455,139, 1 gene (within-gene range 0–2): SBF1P1.
- chr10:23,343,957–23,345,181, 1 gene (within-gene range 0–2): AL606469.1.
- chr12:129,839,928–129,840,522, 1 gene (within-gene range 0–2): AC055717.3.
- chr13:100,062,296–100,063,601, 1 gene: ASNSP3.
- chr14:100,143,957–100,159,645, 1 gene (within-gene range 0–2): DEGS2.
- chr15:25,174,927–25,225,284, 28 genes (within-gene range 0–2): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:25,232,387–25,250,940, 11 genes (within-gene range 0–2): SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:87,830,023–87,869,507, 3 genes: SLC7A5, MIR6775, AC126696.2.
- chr17:1,022,476–1,022,559, 1 gene (within-gene range 0–1): MIR3183.
- chr17:75,498,548–75,498,628, 1 gene (within-gene range 0–2): MIR6785.
- chr17:81,189,593–81,222,999, 2 genes: CEP131, AC027601.2.
- chr19:4,969,113–5,153,598, 1 gene: KDM4B.
- chr20:62,302,093–62,367,312, 5 genes (within-gene range 0–2): ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1.
- chr20:63,939,829–63,956,985, 4 genes (within-gene range 0–1): UCKL1, MIR1914, MIR647, UCKL1-AS1.
- chr20:63,974,116–63,980,008, 1 gene (within-gene range 0–1): SAMD10.
- chr20:64,047,582–64,049,639, 1 gene (within-gene range 0–1): SOX18.
- chr21:44,300,051–44,339,402, 4 genes (within-gene range 0–2): PFKL, AP001062.3, CFAP410, AP001062.1.
- chr21:44,350,163–44,443,081, 4 genes: TRPM2, TRPM2-AS, AP001065.2, AP001065.1.
- chr22:41,938,737–41,947,152, 1 gene: CENPM.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,780. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
